Somatic mutation profile of tumor specimen TCGA-X6-A8C6-01A (aliquot TCGA-X6-A8C6-01A-11D-A36J-09) from TCGA case TCGA-X6-A8C6, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Fibromyxosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 55.0 years (20,090 days).
Specimen TCGA-X6-A8C6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 42f8cb3e-5bab-4f87-9063-189431d9ef09.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-X6-A8C6-10A (Blood Derived Normal), aliquot TCGA-X6-A8C6-10A-01D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3062662-a13a-4d43-b4a1-2fb2a35f676d

The open-access MAF lists 50 somatic variants for this specimen: 41 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 8, Frame Shift Del 5, Splice Site 2, Nonsense Mutation 2, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1A | c.4055G>A p.R1352Q | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1057520918, CM100462, COSV100802498; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACTC1 | c.976A>T p.T326S | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated, low confidence (0.67); PolyPhen possibly damaging (0.551); catalogued as COSV99291867; called by muse, mutect2
- AGMAT | c.635G>A p.G212D | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.35); catalogued as COSV101011786; called by muse, mutect2, varscan2
- APCDD1L | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100953942; called by muse, mutect2, varscan2
- BST1 | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs958935555, COSV53945635; called by muse, mutect2
- CACNA1G | c.503C>T p.S168L | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.362); catalogued as rs1254989551, COSV100661874; called by muse, mutect2, varscan2
- CACNG3 | c.589G>A p.V197M | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs771940327, COSV99136254; called by muse, mutect2, varscan2
- CCDC113 | c.707T>C p.I236T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as rs1259783589, COSV99540971; called by muse, mutect2, varscan2
- CDH12 | c.1913G>A p.R638Q | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs772189448, COSV66392948; called by muse, mutect2, varscan2
- CHD7 | c.6106C>T p.P2036S | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV101418257; called by muse, mutect2, varscan2
- FOXL1 | c.703C>A p.R235S | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100206278; called by muse, mutect2
- HMOX1 | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs201083816; called by muse, mutect2, varscan2
- KDR | c.1394A>G p.E465G | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.122); catalogued as COSV99817803; called by muse, mutect2, varscan2
- KIR2DL1 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 54/178 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.614); catalogued as COSV99383119; called by muse, mutect2, varscan2
- KMT2E | c.2965G>A p.E989K | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.081); catalogued as COSV99996362; called by muse, mutect2, varscan2
- LAMA4 | c.663T>A p.C221* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as COSV100038447; called by muse, mutect2, varscan2
- NDUFV3 | c.176C>T p.A59V (on ENST00000340344 / NM_001001503.2; = p.A424V on NM_021075.4) | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100447020; called by muse, mutect2
- PCDHA11 | c.2125C>A p.L709I | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.751); catalogued as COSV100250698, COSV56475927; called by muse, mutect2, varscan2
- PCDHA3 | c.1468G>A p.V490M | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1554122266, COSV100793480, COSV63540920; called by muse, mutect2, varscan2
- PCDHA7 | c.439C>G p.P147A | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.02); catalogued as COSV100971501; called by muse, mutect2, varscan2
- PEX5L | c.1136C>G p.A379G | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as COSV99828861; called by muse, mutect2
- PHRF1 | c.907C>T p.R303C | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.2); catalogued as rs1199118826, COSV52761892; called by muse, mutect2, varscan2
- PKHD1 | c.6442G>T p.E2148* | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | catalogued as COSV100583221; called by muse, mutect2, varscan2
- PLCG1 | c.2498A>G p.Y833C | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.35); catalogued as rs1311007779, COSV99718917; called by muse, mutect2
- PLPPR1 | c.677T>G p.L226R | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV100883299; called by muse, mutect2
- RBP2 | c.298G>A p.G100R | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99218364; called by muse, mutect2, varscan2
- RTEL1 | c.3560A>G p.Q1187R | Missense Mutation (SNP) | VAF 71/331 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV99423003; called by muse, mutect2, varscan2
- RYR2 | c.7963A>G p.K2655E | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100770433; called by muse, mutect2, varscan2
- TBC1D1 | c.2962+1G>A p.X988_splice | Splice Site (SNP) | VAF 5/47 reads (11%) | catalogued as COSV99791323; called by muse, mutect2, varscan2
- TBCD | c.1427G>A p.R476H | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1206646550, COSV100833274; called by muse, mutect2, varscan2
- UNC13A | c.3386C>T p.T1129M | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs953780016, COSV53194995, COSV99406684; called by muse, mutect2, varscan2
- USP13 | c.1007C>T p.T336M | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200851300, COSV99831187; called by mutect2, varscan2
- ZBBX | c.1325T>C p.I442T | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.051); catalogued as COSV100284095; called by muse, mutect2, varscan2
- ZCCHC17 | c.585_586del p.H195Qfs*3 | Frame Shift Del (DEL) | VAF 6/17 reads (35%) | catalogued as rs1330878964; called by mutect2, pindel, varscan2
- ZXDC | c.653C>T p.A218V | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs1433845535, COSV100306475; called by muse, mutect2, varscan2
- EPHA7 | c.2765del p.F922Sfs*34 | Frame Shift Del (DEL) | VAF 9/57 reads (16%) | called by mutect2, pindel, varscan2
- ERVFRD-1 | c.263del p.P88Lfs*9 | Frame Shift Del (DEL) | VAF 15/89 reads (17%) | called by mutect2, pindel, varscan2
- IL12RB2 | c.480-12_480del p.X160_splice | Splice Site (DEL) | VAF 15/76 reads (20%) | called by mutect2, pindel, varscan2
- KRT72 | c.1523dup p.A509Gfs*12 | Frame Shift Ins (INS) | VAF 11/43 reads (26%) | called by mutect2, pindel, varscan2
- LRP10 | c.1634_1635del p.R545Pfs*32 | Frame Shift Del (DEL) | VAF 16/52 reads (31%) | called by mutect2, pindel, varscan2
- PDS5A | c.1606_1609del p.F536Efs*3 | Frame Shift Del (DEL) | VAF 17/62 reads (27%) | called by mutect2, pindel, varscan2
- ADGRA3 | c.3654G>A p.S1218= | Silent (SNP) | VAF 21/107 reads (20%) | catalogued as rs865846039, COSV51568501, COSV99293318; called by muse, mutect2, varscan2
- AMBRA1 | c.2793G>T p.L931= (on ENST00000458649 / NM_001367468.1; = p.L841= on NM_017749.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as COSV100094081; called by muse, mutect2, varscan2
- CRYBB2 | c.63C>A p.I21= | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as rs1368825193, COSV68005750; called by muse, mutect2, varscan2
- FBN1 | c.8064T>C p.S2688= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV100355195; called by muse, mutect2, varscan2
- NFRKB | c.3318C>T p.T1106= (on ENST00000446488 / NM_001143835.2; = p.T1131= on NM_006165.3) | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs371098164; called by muse, mutect2, varscan2
- NOC4L | c.480T>A p.P160= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV100223071; called by muse, mutect2, varscan2
- PITPNM1 | c.3084C>T p.D1028= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs370108604; called by muse, mutect2, varscan2
- SIM1 | c.1122G>T p.R374= | Silent (SNP) | VAF 7/88 reads (8%) | catalogued as COSV99492393; called by muse, mutect2
- OR3A4P | n.391G>C | RNA (SNP) | VAF 10/69 reads (14%) | called by muse, mutect2, varscan2
